Gene-level copy-number profile of tumor specimen C3L-08236-01 from CPTAC case C3L-08236, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 73.2 years (26,741 days).
Specimen C3L-08236-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 24719656-a413-4d82-a259-6f41189f66a2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08236-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/732e49f0-6f96-49d1-b198-dc7c27f38575

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 239; copy number 2: 17,139; copy number 3: 20,711; copy number 4: 13,969; copy number 5: 3,959; copy number 6: 872; copy number 7: 343; copy number 8: 1,073; copy number 10: 16; copy number 11: 1; copy number 12: 2; copy number 13: 11; copy number 14: 10; copy number 16: 19; copy number 17: 5; copy number 23: 10; copy number 31: 4; copy number 72: 2; copy number 95: 2; copy number 119: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,503 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:43,336,164–43,348,716, 1 gene, copy number 11: AC114947.1.
- chr9:34,989,641–36,677,683, 73 genes, copy number 8–23 (broad region; genes not listed).
- chr12:58,872,149–60,269,686, 16 genes, copy number 10–16: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 7–8 (broad region; genes not listed).
- chr20:53,544,615–54,651,169, 14 genes, copy number 8–119: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5.
- chr20:57,105,741–59,847,711, 69 genes, copy number 7–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
